CPTAC case C287328 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/838cd4b5-7c3a-4794-9909-b48b21fafef6

Demographics
Sex at birth: male; Age at index: 47 years; Vital status: Dead; Days to death: 664 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Temporal lobe; Tumor grade: G4; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 664 days (1.8 years); Progression or recurrence: yes; Days to recurrence: 430 days (1.2 years); Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: No.

Biospecimens (9 samples)
- Samples 1104760, 1105223, SM-JU34R (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1104790, 1105253, SM-JU34F (3 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105211: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample C287328-TP: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Left; Preservation method: Snap Frozen.
- Sample C287328-TR1: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Left; Preservation method: Snap Frozen.
